Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6535, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6535-01A (Primary Tumor).

Examination: Histopathological examination

CGA - D5 - 6535

Material: Partial organ resection – colon ascending

Material collected on: Material received on:

Expected time of examination:

Clinical diagnosis:

Examination performed on:

Macroscopic description:

A 15.6 cm length of large intestine with periintestinal fat tissue sized 16.3 x 8.4 x 3.3 cm and appendix of 5cm. Ulcerous tumour sized 6.3 x 6.2 x 2.8 cm in the mucosa. Tumor covers 100% of the circumference of the intestine and narrows its lumen.

Microscopic description:

Adenocarcinoma tubulopapillare (G2). Tubulopapillar adenocarcinoma (G2)

Infiltratio carcinomatosa telae adiposae pericolicae.

Incision lines free of neoplastic lesions.

Outside the tumor: Adenomata tubulopapillaria cum dysplasia gradus minoris

Metastases carcinomatosae in lymphonodo No I/VI. Cancer metastases in lymph nodes No I/VI

Emboliae carcinomatosae

Histopathological diagnosis

Adenocarcinoma tubulopapillare coli. Tubulopapillar adenocarcinoma of the colon
(G2, Dukes C, Astler - Coller C2, pT3, pN1)

Source: NCI Genomic Data Commons file 7ca948f8-2e6e-4319-b3c2-e5783725c302 (TCGA-D5-6535.59BA1E59-3E20-40A9-9068-09FC324845E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).